Somatic mutation profile of tumor specimen TCGA-50-5939-01A (aliquot TCGA-50-5939-01A-11D-1625-08) from TCGA case TCGA-50-5939, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 85.5 years (31,236 days).
Specimen TCGA-50-5939-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19aa1736-30b3-4ed9-b827-373a79b8de70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5939-11A (Solid Tissue Normal), aliquot TCGA-50-5939-11A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72c46029-bf04-4eda-a7ea-cc7242253294

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 5, Intron 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOT | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs121908457, CM023181, COSV53514808; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by mutect2, varscan2
- ADGRG4 | c.8795G>A p.R2932Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs980343377, COSV54951498; called by muse, mutect2, varscan2
- AHNAK2 | c.8061G>A p.M2687I | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100314912; called by muse, mutect2
- ANKRD26 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV65774940, COSV65775491; called by muse, mutect2, varscan2
- ANO10 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372086237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.4159G>C p.A1387P | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51935216; called by muse, mutect2, varscan2
- ARAP1 | c.2237A>C p.H746P (on ENST00000393609 / NM_001040118.2; = p.H501P on NM_015242.4) | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV61991154; called by muse, mutect2, varscan2
- ATXN1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs554480203, COSV55216470, COSV99787288; called by muse, mutect2, varscan2
- BUB1B | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs557521971, COSV55012531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf90 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.579); catalogued as rs148312578; called by muse, mutect2, varscan2
- CDK12 | c.4099G>C p.V1367L (on ENST00000447079 / NM_016507.4; = p.V1358L on NM_015083.3) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV71000660, COSV71001028; called by muse, mutect2, varscan2
- CTNNA1 | c.2707A>G p.M903V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV57073854; called by muse, mutect2, varscan2
- DOK1 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV51207555; called by muse, mutect2, varscan2
- DSC1 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV57145682; called by muse, mutect2, varscan2
- DSN1 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs747511912, COSV101041083, COSV65519173; called by muse, mutect2, varscan2
- DYNC1H1 | c.10414G>C p.V3472L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64136957; called by muse, mutect2, varscan2
- ENAM | c.1413T>A p.Y471* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV68535939; called by muse, mutect2, varscan2
- FAM3D | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62558283; called by muse, mutect2, varscan2
- FCER1A | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV63667226, COSV63667320; called by muse, mutect2, varscan2
- HAUS3 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV54722709; called by muse, mutect2, varscan2
- HMGCS2 | c.861T>A p.D287E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV65567882; called by muse, mutect2, varscan2
- ITSN1 | c.2917A>G p.I973V | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1448509034, COSV66083019; called by muse, mutect2, varscan2
- KEAP1 | c.782G>C p.R261P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.806); catalogued as COSV50283722, COSV50651509; called by muse, mutect2, varscan2
- KIAA0319L | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs755794086, COSV57847424; called by muse, mutect2, varscan2
- KMT2C | c.12495G>T p.Q4165H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV51439276; called by muse, mutect2, varscan2
- LMO4 | c.286G>C p.A96P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV100983959; called by muse, mutect2, varscan2
- LRRC8B | c.2273A>G p.N758S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100446377; called by muse, mutect2, varscan2
- LRRIQ1 | c.1256A>C p.K419T | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV67830755; called by muse, mutect2, varscan2
- LRRTM3 | c.90del p.E31Nfs*34 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as COSV100791510; called by mutect2, pindel
- LSM11 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477236195, COSV53848169; called by muse, mutect2, varscan2
- MYO16 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs771164441, COSV51792802; called by muse, mutect2, varscan2
- MYO1C | c.3106G>A p.D1036N (on ENST00000648651 / NM_001080779.2; = p.D1001N on NM_033375.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV62999104; called by muse, mutect2, varscan2
- NAV3 | c.4225A>T p.T1409S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.863); catalogued as COSV99885675; called by muse, mutect2, varscan2
- NAV3 | c.4226C>G p.T1409S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.863); catalogued as COSV99885677; called by muse, mutect2, varscan2
- NLRP1 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs149973177, COSV52566151; called by muse, mutect2, varscan2
- NMUR2 | c.814G>T p.V272F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV54919274; called by muse, mutect2, varscan2
- NRDC | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV61404318; called by muse, mutect2, varscan2
- OR4D1 | c.491T>A p.L164H | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99273980; called by muse, mutect2, varscan2
- OR5A1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.315); catalogued as rs1471420188, COSV57376694; called by muse, mutect2, varscan2
- OR8H3 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as COSV57908144, COSV57908895; called by muse, mutect2, varscan2
- PHKA2 | c.2255G>A p.R752K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs774591968, COSV66053931; called by muse, mutect2, varscan2
- POLK | c.2471G>T p.S824I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV54035170; called by muse, mutect2, varscan2
- PTH1R | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs572975854, COSV57315684, COSV57315775; called by muse, mutect2, varscan2
- RAG1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55025283; called by muse, mutect2, varscan2
- SH2D3C | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.502); catalogued as COSV59122830; called by muse, mutect2
- SLC27A3 | c.446A>G p.H149R (on ENST00000271857; = p.H21R on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs752469654, COSV55163566; called by muse, mutect2, varscan2
- SLC35G1 | c.362C>T p.T121I (on ENST00000427197 / NM_001134658.3; = p.T120I on NM_153226.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs766872870, COSV101003995; called by muse, mutect2
- TRIB1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100322318, COSV61334099; called by muse, mutect2, varscan2
- TTC37 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV62454777; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1698C>G p.I566M | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV51955475; called by muse, mutect2
- WDR11 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54788388; called by muse, mutect2
- WNT4 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.446); catalogued as rs955716881, COSV99268565; called by muse, mutect2, varscan2
- XIRP2 | c.8193G>C p.E2731D (on ENST00000628543; = p.E2906D on NM_152381.6) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1402575913, COSV54700136, COSV99737966; called by muse, mutect2, varscan2
- ZNF302 | c.716C>T p.S239L (on ENST00000627982; = p.S160L on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV101416418; called by mutect2, varscan2
- ACACA | c.5408C>G p.S1803C | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CTDSP1 | c.123dup p.L42Tfs*9 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- NFE2 | c.709_717del p.F237_T239del | In Frame Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.1971_1972insTTACAA p.L656_Q657dup | In Frame Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- AADACL3 | c.528C>A p.S176= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV60199056, COSV60199164; called by muse, mutect2, varscan2
- AKR1E2 | c.429C>G p.P143= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV53630471; called by muse, mutect2, varscan2
- ATP10B | c.192G>A p.R64= | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as COSV58778046, COSV58778794; called by muse, mutect2, varscan2
- CNTNAP4 | c.2604C>A p.P868= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV100268861; called by muse, mutect2
- COL5A2 | c.699A>G p.A233= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV66409760; called by muse, mutect2
- DMD | c.5617C>T p.L1873= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV63754913; called by muse, mutect2, varscan2
- HNRNPA1 | c.183A>G p.T61= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52936822; called by muse, mutect2, varscan2
- KRT1 | c.90G>A p.R30= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1190118432, COSV52866781, COSV99358970; called by muse, mutect2, varscan2
- LRRC4C | c.1218C>A p.L406= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV53420720, COSV53425689; called by muse, mutect2, varscan2
- MOCOS | c.639G>A p.L213= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV54343388; called by muse, mutect2, varscan2
- NLGN2 | c.465C>T p.L155= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV57210194; called by muse, mutect2
- P2RY6 | c.333C>T p.H111= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs567246681, COSV62936593; called by muse, mutect2, varscan2
- PDZD7 | c.621C>T p.V207= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100931529; called by muse, mutect2
- PUM3 | c.1533G>T p.V511= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV65896720; called by muse, mutect2, varscan2
- TRAP1 | c.852C>T p.P284= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs755984821, COSV55916266; called by muse, mutect2, varscan2
- MYADM | chr19:53874499 G>A | 3'Flank (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100424885; called by muse, mutect2
- PCLO | c.14791+9C>T | Intron (SNP) | VAF 21/118 reads (18%) | catalogued as COSV61616495; called by muse, mutect2, varscan2
- RCAN1 | c.253-2971C>T | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100571531; called by muse, mutect2, varscan2
